Somatic mutation profile of tumor specimen C3N-01362-01 (aliquot CPT0380070009) from CPTAC case C3N-01362, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oncocytoma; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 59.6 years (21,766 days).
Specimen C3N-01362-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c87b7bb-c377-42aa-aafc-efd378cf69e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01362-31 (Blood Derived Normal), aliquot CPT0380340002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84e59efb-517d-479e-9d26-27a12be4851f

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 8, Silent 4, Nonsense Mutation 2, Frame Shift Ins 1, Nonstop Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAHCC1 | c.380C>T p.S127L | Missense Mutation (SNP) | VAF 11/226 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781890318, COSV57031869; called by muse, mutect2
- NAT1 | c.208C>T p.Q70* | Nonsense Mutation (SNP) | VAF 34/140 reads (24%) | catalogued as COSV100306507; called by muse, mutect2, varscan2
- TMUB2 | c.289A>G p.T97A (on ENST00000538716 / NM_001353177.2; = p.T77A on NM_024107.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746108679; called by muse, mutect2, varscan2
- AKAP13 | c.8335C>T p.P2779S (on ENST00000394518 / NM_007200.5; = p.P2783S on NM_006738.6) | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); called by mutect2, varscan2
- AP002748.5 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 36/289 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- BARD1 | c.952A>T p.N318Y | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.87); PolyPhen benign (0.086); called by mutect2, varscan2
- DNAH2 | c.2365del p.Q789Sfs*4 | Frame Shift Del (DEL) | VAF 62/305 reads (20%) | called by mutect2, pindel, varscan2
- FDPS | c.1162dup p.Y388Lfs*9 | Frame Shift Ins (INS) | VAF 63/467 reads (13%) | called by mutect2, pindel, varscan2
- HDAC3 | c.22T>A p.F8I | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2
- LTB | c.733T>A p.*245Rext*27 | Nonstop Mutation (SNP) | VAF 7/50 reads (14%) | called by muse, varscan2
- PCDHB12 | c.784G>T p.V262L | Missense Mutation (SNP) | VAF 60/175 reads (34%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- POLD3 | c.578T>A p.M193K | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2
- ZNF48 | c.1603C>T p.Q535* | Nonsense Mutation (SNP) | VAF 51/177 reads (29%) | called by muse, mutect2, varscan2
- ATN1 | c.2112C>T p.G704= | Silent (SNP) | VAF 8/114 reads (7%) | called by muse, mutect2
- ATP1A4 | c.1746A>T p.I582= | Silent (SNP) | VAF 49/169 reads (29%) | called by muse, mutect2, varscan2
- PTGIS | c.249C>T p.Y83= | Silent (SNP) | VAF 37/260 reads (14%) | catalogued as rs201680738; called by muse, mutect2, varscan2
- SP1 | c.876G>A p.Q292= (on ENST00000327443 / NM_138473.3; = p.Q285= on NM_003109.1) | Silent (SNP) | VAF 11/242 reads (5%) | catalogued as rs933786272; called by muse, mutect2
